Somatic mutation profile of tumor specimen TCGA-56-8309-01A (aliquot TCGA-56-8309-01A-11D-2293-08) from TCGA case TCGA-56-8309, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66.8 years (24,382 days).
Specimen TCGA-56-8309-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d975a44a-331c-4fa7-8e1a-4254cbbe0b92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8309-10A (Blood Derived Normal), aliquot TCGA-56-8309-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e570a520-1493-4dc4-8f54-1eec12bd26a3

The open-access MAF lists 135 somatic variants for this specimen: 113 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 21, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 16/125 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786201044, CM004336, COSV100911109, COSV64289087; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTG1 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59509690; called by muse, mutect2, varscan2
- ADAM15 | c.2423A>G p.K808R (on ENST00000356955 / NM_207197.3; = p.K783R on NM_207195.3) | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.388); catalogued as COSV99664757; called by muse, mutect2, varscan2
- ADAM15 | c.2424G>T p.K808N (on ENST00000356955 / NM_207197.3; = p.K783N on NM_207195.3) | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV55127791, COSV99664760; called by muse, mutect2, varscan2
- ADAMTS16 | c.1796C>A p.S599Y | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99940266; called by muse, mutect2, varscan2
- ADGRG4 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs757949458, COSV99794544; called by muse, mutect2, varscan2
- AGGF1 | c.152A>G p.H51R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV100461565; called by muse, mutect2, varscan2
- ANGPT4 | c.1295C>A p.T432N | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769815616, COSV67920962, COSV67922848; called by muse, mutect2, varscan2
- APAF1 | c.2539G>T p.D847Y (on ENST00000551964 / NM_181861.2; = p.D836Y on NM_013229.3) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV100452322; called by muse, mutect2, varscan2
- ARHGAP36 | c.1234G>T p.V412F | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99357313; called by muse, mutect2, varscan2
- ASGR2 | c.716A>G p.D239G | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV99642892; called by muse, mutect2, varscan2
- ATIC | c.1049C>G p.A350G | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99377522; called by muse, mutect2, varscan2
- BAMBI | c.310T>C p.C104R | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100977486; called by muse, mutect2, varscan2
- BUB3 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100922122; called by muse, mutect2, varscan2
- CENPE | c.7123G>A p.A2375T | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as rs1337414118, COSV99477138; called by muse, mutect2
- CHD5 | c.3191G>C p.G1064A | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99312667; called by muse, mutect2
- CHEK2 | c.1315C>G p.L439V (on ENST00000382580 / NM_001005735.2; = p.L396V on NM_007194.4) | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs886041172, COSV60415131; ClinVar: uncertain significance; called by muse, mutect2
- CNR1 | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.005); catalogued as COSV100759165; called by muse, mutect2, varscan2
- COG7 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.089); catalogued as rs1431608859, COSV100207393; called by muse, mutect2, varscan2
- COL11A1 | c.1630G>T p.G544W | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100615383, COSV99071322; called by muse, mutect2, varscan2
- COPG2 | c.322A>C p.S108R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100449583; called by muse, mutect2
- CYB5R4 | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100859638; called by muse, mutect2, varscan2
- CYP3A43 | c.1190C>G p.P397R | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99732959; called by muse, mutect2, varscan2
- CYTH2 | c.1068C>G p.I356M (on ENST00000427476; = p.I355M on NM_004228.7) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); catalogued as rs900643788, COSV100287064; called by muse, mutect2, varscan2
- DCDC2 | c.1193A>T p.Q398L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV101015262; called by muse, mutect2, varscan2
- DIRAS1 | c.138G>C p.Q46H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV100052968; called by muse, mutect2, varscan2
- DLG2 | c.218A>G p.E73G (on ENST00000650630 / NM_001351274.2; = p.E36G on NM_001142699.3) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV101070356; called by muse, mutect2, varscan2
- DLL1 | c.453G>C p.R151S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV100815946; called by muse, mutect2, varscan2
- DOCK7 | c.3168A>G p.I1056M (on ENST00000635253 / NM_001367561.1; = p.I1025M on NM_033407.3) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV99223164; called by muse, mutect2, varscan2
- EMILIN2 | c.1690A>T p.M564L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99598190; called by muse, mutect2, varscan2
- ENAM | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV101252951; called by muse, mutect2
- EPHA6 | c.1850A>G p.Y617C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV101061030; called by muse, mutect2, varscan2
- EPHA6 | c.2722G>C p.V908L (on ENST00000389672 / NM_001080448.3; = p.V300L on NM_173655.4) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV67569727; called by muse, mutect2, varscan2
- EPYC | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99664507; called by muse, mutect2
- EYS | c.1352T>C p.V451A | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1245770502, COSV100675797; called by muse, mutect2
- FAM170A | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs867555282, COSV100088784; called by muse, mutect2, varscan2
- FGF14 | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV101084920; called by muse, mutect2
- FGF19 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV99594276; called by muse, mutect2, varscan2
- GASK1B | c.434T>C p.L145S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV99647340; called by muse, mutect2
- GIMAP1 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252849252, COSV100211967, COSV56189089; called by muse, mutect2, varscan2
- GLRA3 | c.1358T>A p.I453N | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as COSV99927091; called by muse, mutect2, varscan2
- GRIA2 | c.1805T>A p.L602* | Nonsense Mutation (SNP) | VAF 19/151 reads (13%) | catalogued as COSV99643244; called by muse, mutect2, varscan2
- HCN1 | c.2125C>A p.Q709K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.237); catalogued as COSV100298893; called by muse, mutect2, varscan2
- HELZ | c.2993C>T p.T998I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100698541; called by muse, mutect2, varscan2
- HOOK2 | c.1964A>C p.Q655P | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV99317362; called by muse, mutect2, varscan2
- HTR5A | c.353T>A p.I118N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99839484; called by muse, mutect2
- HTR5A | c.355G>C p.A119P | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV99839487; called by muse, mutect2
- HTRA3 | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.281); catalogued as COSV100246231; called by muse, mutect2, varscan2
- INSR | c.926A>G p.N309S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.388); catalogued as COSV100251607; called by muse, mutect2, varscan2
- INTS1 | c.3478G>C p.A1160P | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV101247519; called by muse, mutect2, varscan2
- ITPRIPL2 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV101198143; called by muse, mutect2, varscan2
- KLHL32 | c.598A>T p.T200S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.198); catalogued as COSV100987172; called by muse, mutect2, varscan2
- KMT2A | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.268); catalogued as COSV100628114, COSV63282866; called by muse, mutect2, varscan2
- LIG4 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100799723; called by muse, mutect2, varscan2
- LRBA | c.7494G>T p.L2498F | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100841019; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2065G>T p.V689L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.992); catalogued as rs1194869207, COSV99167720; called by muse, mutect2, varscan2
- MCF2L2 | c.2302-1G>A p.X768_splice | Splice Site (SNP) | VAF 11/89 reads (12%) | catalogued as COSV100191535; called by muse, mutect2, varscan2
- MYBPC3 | c.3347T>C p.L1116S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as rs886038832, COSV99919981; ClinVar: uncertain significance; called by mutect2, varscan2
- NCOR1 | c.5038T>G p.Y1680D | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99247929; called by muse, mutect2, varscan2
- NINL | c.1373G>T p.R458L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs189239829, COSV54002077; called by muse, mutect2, varscan2
- NOS1 | c.2961A>C p.Q987H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV100500133; called by muse, varscan2
- NUP205 | c.4821G>C p.M1607I | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99606548; called by muse, mutect2, varscan2
- OR10A5 | c.688C>G p.P230A | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV100203380; called by muse, mutect2, varscan2
- OR10S1 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.119); catalogued as COSV101602448; called by muse, mutect2, varscan2
- OR14K1 | c.416G>C p.C139S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV99314981; called by muse, mutect2, varscan2
- OR2M4 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | catalogued as COSV60708985; called by muse, mutect2, varscan2
- OR4S2 | c.518A>C p.D173A | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100412570; called by muse, mutect2, varscan2
- OR5B21 | c.407C>G p.A136G | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as COSV100835098; called by muse, mutect2, varscan2
- ORC1 | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.602); catalogued as COSV100856601, COSV65363533; called by muse, mutect2, varscan2
- PAFAH2 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100959210; called by muse, mutect2, varscan2
- PCDHGA2 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.025); catalogued as rs993292970, COSV53927820, COSV99533996; called by muse, mutect2, varscan2
- PDZD2 | c.6203C>G p.P2068R | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV99223968; called by muse, mutect2, varscan2
- PHF2 | c.2404G>T p.A802S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100823049; called by muse, mutect2, varscan2
- PPP1R21 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.806); catalogued as COSV99681722; called by muse, mutect2
- PPP1R3A | c.1170C>A p.C390* | Nonsense Mutation (SNP) | VAF 28/177 reads (16%) | catalogued as rs771743186, COSV99492117; called by muse, mutect2, varscan2
- PRRT2 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs757132796, COSV99569271; called by mutect2, varscan2
- PTPN2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100518378; called by muse, mutect2, varscan2
- RAC1 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100640962; called by muse, mutect2
- RBM26 | c.248C>G p.P83R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99935874; called by muse, mutect2, varscan2
- REST | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58360028; called by muse, mutect2, varscan2
- SELE | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 14/106 reads (13%) | catalogued as rs759220052, COSV60975477; called by muse, mutect2, varscan2
- SHPRH | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV99260984, COSV99261427; called by muse, mutect2, varscan2
- SIGLEC14 | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99707186; called by muse, mutect2, varscan2
- SLAMF9 | c.365T>C p.M122T | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100928109; called by muse, mutect2
- SLC16A14 | c.1316C>A p.A439D | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99725252; called by muse, mutect2, varscan2
- SLC26A1 | c.89T>A p.M30K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99925730; called by muse, mutect2
- SLC26A7 | c.194-1G>C p.X65_splice | Splice Site (SNP) | VAF 16/96 reads (17%) | catalogued as COSV52603919, COSV99402726; called by muse, mutect2, varscan2
- SNTG2 | c.1235G>T p.W412L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100421628, COSV58003059; called by muse, mutect2
- SNTG2 | c.1236G>T p.W412C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100421629; called by muse, mutect2
- SORCS1 | c.2648A>G p.Y883C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99543868; called by muse, mutect2
- ST6GALNAC4 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | PolyPhen probably damaging (0.991); catalogued as COSV100231328; called by muse, mutect2
- STAT3 | c.1199A>T p.N400I | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV52893350, COSV99232462; called by muse, mutect2, varscan2
- STEAP4 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.475); catalogued as rs1385096591, COSV100112417; called by muse, mutect2, varscan2
- TBX21 | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as COSV99455886; called by muse, mutect2, varscan2
- TRAF7 | c.1139A>T p.Y380F | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100399171; called by muse, mutect2, varscan2
- TRIM54 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99940500; called by muse, mutect2, varscan2
- TRIM55 | c.459C>G p.H153Q | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765541654, COSV99396558; called by muse, mutect2
- TTN | c.22829G>C p.R7610T (on ENST00000591111; = p.R6683T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | PolyPhen benign (0.05); catalogued as COSV100597486, COSV60387505; called by muse, mutect2, varscan2
- UBE2J2 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV100231058; called by muse, mutect2, varscan2
- USP24 | c.4153C>A p.P1385T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.017); catalogued as COSV99598972; called by muse, mutect2, varscan2
- WASHC5 | c.1463A>G p.Y488C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.819); catalogued as COSV100572600; called by muse, mutect2, varscan2
- ZDHHC6 | c.199A>G p.M67V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV101024336; called by muse, mutect2, varscan2
- ZNF215 | c.554T>C p.V185A | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.253); catalogued as COSV99549249; called by muse, mutect2, varscan2
- ZNF426 | c.1427A>G p.Y476C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1227454009, COSV99464994; called by muse, mutect2, varscan2
- ZNF80 | c.576T>A p.S192R | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as COSV100351931; called by muse, mutect2, varscan2
- ZNF804B | c.3293T>C p.L1098P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as rs761456230, COSV100302154; called by muse, mutect2, varscan2
- IGHV1-45 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- KRT23 | c.480-2del p.X160_splice | Splice Site (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel, varscan2
- NCKAP1L | c.2945del p.N982Ifs*2 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- NFKBIA | c.391del p.L131Wfs*33 | Frame Shift Del (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel
- POTEA | c.1384C>A p.Q462K (on ENST00000519951 / NM_001005365.2; = p.Q416K on NM_001002920.1) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SPANXB1 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); called by muse, mutect2
- ADAMTS15 | c.1791C>T p.L597= | Silent (SNP) | VAF 29/185 reads (16%) | catalogued as COSV100143128; called by muse, mutect2, varscan2
- CCDC38 | c.1248T>C p.F416= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs1209586617, COSV100717408; called by muse, mutect2, varscan2
- CNN1 | c.354A>T p.T118= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as COSV99372229; called by muse, mutect2, varscan2
- FAM135B | c.1128C>A p.S376= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV52711894, COSV99419820; called by muse, mutect2, varscan2
- GDF3 | c.906C>A p.T302= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV100325128; called by muse, mutect2, varscan2
- GRM1 | c.2274C>G p.G758= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV99264469; called by muse, mutect2, varscan2
- LENG8 | c.946C>T p.L316= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100457185; called by muse, mutect2, varscan2
- LPAR4 | c.867A>G p.A289= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV101425082; called by muse, mutect2, varscan2
- LRRC43 | c.1782G>A p.L594= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV60288771; called by muse, mutect2, varscan2
- MYH11 | c.5685C>A p.R1895= | Silent (SNP) | VAF 19/225 reads (8%) | catalogued as COSV100257886; called by muse, mutect2
- MYH6 | c.229T>C p.L77= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV100676330; called by muse, mutect2, varscan2
- OR10G7 | c.477C>T p.T159= | Silent (SNP) | VAF 24/242 reads (10%) | catalogued as COSV100389789; called by muse, mutect2, varscan2
- OR5H14 | c.783C>A p.G261= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV101454090; called by muse, mutect2, varscan2
- PHYH | c.705G>T p.G235= | Silent (SNP) | VAF 52/479 reads (11%) | catalogued as COSV99538027; called by muse, mutect2, varscan2
- PKHD1L1 | c.8001C>A p.A2667= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV101005527, COSV65740368; called by muse, mutect2, varscan2
- STAC2 | c.639C>A p.S213= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as COSV100336288; called by muse, mutect2
- TRIP13 | c.135A>G p.L45= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99386230; called by muse, mutect2, varscan2
- USH2A | c.7962G>A p.V2654= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs767004210, COSV100230099; called by muse, mutect2, varscan2
- USP7 | c.1803G>T p.S601= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV100784003; called by muse, mutect2, varscan2
- ZNF25 | c.984C>T p.A328= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100224514; called by muse, mutect2, varscan2
- ZNF398 | c.1164C>T p.T388= (on ENST00000475153 / NM_170686.3; = p.T217= on NM_020781.4) | Silent (SNP) | VAF 18/142 reads (13%) | catalogued as rs959808804, COSV100246824; called by muse, mutect2, varscan2
- C3P1 | n.2554C>A | RNA (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
